Somatic mutation profile of tumor specimen MP2PRT-PASZYC-TMP1-A (aliquot MP2PRT-PASZYC-TMP1-A-1-0-D-A81O-36) from MP2PRT case MP2PRT-PASZYC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.6 years (2,764 days).
Specimen MP2PRT-PASZYC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0fedb2f5-2631-493c-973c-4e906c6df0ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASZYC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASZYC-NB1-A-1-0-D-A81O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc050181-5999-427d-a3cf-b33e031c01e1

The open-access MAF lists 14 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 9, Silent 3, Nonsense Mutation 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB3 | c.2248C>T p.R750W | Missense Mutation (SNP) | VAF 135/411 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs373831196, COSV57247170; called by muse, mutect2, varscan2
- TMEM59L | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 187/463 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV53241654; called by muse, mutect2, varscan2
- CDC42BPG | c.116G>C p.G39A | Missense Mutation (SNP) | VAF 319/776 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- DMRT3 | c.913C>A p.L305I | Missense Mutation (SNP) | VAF 18/540 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.006); called by muse, mutect2
- KDM6A | c.3408_3409insGGC p.M1136_K1137insG | In Frame Ins (INS) | VAF 134/164 reads (82%) | called by mutect2, pindel, varscan2
- NANS | c.818T>C p.L273P | Missense Mutation (SNP) | VAF 224/512 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- NAP1L2 | c.950C>A p.P317H | Missense Mutation (SNP) | VAF 27/307 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ROS1 | c.5591T>C p.L1864P | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- SMIM17 | c.190G>T p.G64W | Missense Mutation (SNP) | VAF 167/472 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TEK | c.2992G>T p.G998* | Nonsense Mutation (SNP) | VAF 113/292 reads (39%) | called by muse, mutect2, varscan2
- ZFP36L2 | c.634T>C p.C212R | Missense Mutation (SNP) | VAF 268/747 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- EPHA8 | c.318C>T p.R106= | Silent (SNP) | VAF 20/733 reads (3%) | catalogued as rs1275281000, COSV51263927; called by muse, mutect2
- OR52N4 | c.57C>G p.V19= | Silent (SNP) | VAF 184/453 reads (41%) | called by muse, mutect2, varscan2
- RASGRF1 | c.2172C>T p.Y724= | Silent (SNP) | VAF 231/554 reads (42%) | catalogued as rs770172047, COSV101174436; ClinVar: likely benign; called by muse, mutect2, varscan2
